Somatic mutation profile of tumor specimen TARGET-20-PASMHY-04A (aliquot TARGET-20-PASMHY-04A-02D) from TARGET case TARGET-20-PASMHY, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 19.1 years (6,979 days).
Specimen TARGET-20-PASMHY-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd398fb5-cd6a-4f65-ac87-99e97b410371.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASMHY-14A (Bone Marrow Normal), aliquot TARGET-20-PASMHY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b190476-c2ce-46f2-b2c8-1eec45a48f7b

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 69/216 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs28941778, CM003970, CM127190, CM910413, COSV60066459, COSV60067963; ClinVar: pathogenic; called by muse, mutect2
- NCOR1 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 69/166 reads (42%) | catalogued as COSV51976279; called by muse, mutect2, varscan2
